Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JA-06A (Metastatic).

ICD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue, back
In 7/24/11 C49.6

DIAGNOSIS

Patient ID - Sample ID -

(A) LEFT BACK, SKIN ELLIPSE:

METASTATIC MALIGNANT MELANOMA WITHIN DEEP DERMIS, FIBROADIPOSE TISSUE, AND SKELETAL MUSCLE. TUMOR SIZE 50 X 40 MM), EXCISED.
MARGINS OF RESECTION FREE OF TUMOR (NEAREST INFERIOR MARGIN, 1.0 MM, yellow, A13).

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RADICAL EXCISIONAL BIOPSY LEFT BACK - A tan-white oriented ellipse of skin (7.0 x 4.0 x 3.5 cm) has a possible scar (3.5 cm in length). The specimen is oriented as short stitch superior side, long stitch lateral tip. The cut surface reveals a white-tan firm nodule (5.0 x 4.0 x 3.5 cm).

INK CODE: Superior - blue; inferior - yellow.

SECTION CODE: The specimen is sectioned sequentially from lateral to medial tip.

A1, lateral tip; A2, medial tip; A3-A24, scar, entirely submitted sequentially from lateral-to-medial including margins; A25, deep margin shaved-inked side down.

CLINICAL HISTORY

Melanoma, back.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

--END OF REPORT-----

Source: NCI Genomic Data Commons file fff13507-e8e4-44d2-9229-654748ee5b45 (TCGA-D3-A2JA.75ADE88D-F7C8-4450-8B93-5706A25A13EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).